Somatic mutation profile of tumor specimen BA2575D (aliquot aq-BA2575D) from BEATAML1.0 case 2043, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, CBF-beta/MYH11; Tissue or organ of origin: Bone marrow; Age at diagnosis: 36.7 years (13,407 days).
Specimen BA2575D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e365682f-8d31-4011-b02d-6f3a69161210.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2445D (Solid Tissue Normal), aliquot aq-BA2445D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ee85c520-88c5-4e6e-96d4-0ad67cfe9d86

The open-access MAF lists 12 somatic variants for this specimen: 4 protein-altering or splice-affecting, 4 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 4, Missense Mutation 3, Intron 2, RNA 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- C2CD3 | c.956-1G>T p.X319_splice | Splice Site (SNP) | VAF 6/120 reads (5%) | called by muse, mutect2
- HEATR5A | c.3104G>T p.G1035V | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); called by muse, mutect2
- KANSL1 | c.375G>T p.L125F | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2
- TTN | c.96082G>T p.V32028F (on ENST00000591111; = p.V24604F on NM_003319.4) | Missense Mutation (SNP) | VAF 6/122 reads (5%) | PolyPhen probably damaging (0.958); called by muse, mutect2
- BRCA2 | c.3279C>A p.S1093= | Silent (SNP) | VAF 3/43 reads (7%) | called by muse, mutect2
- LOXHD1 | c.2400G>T p.V800= | Silent (SNP) | VAF 4/34 reads (12%) | called by muse, mutect2
- SCN8A | c.3291C>A p.P1097= | Silent (SNP) | VAF 4/40 reads (10%) | called by muse, mutect2
- TCF25 | c.150C>A p.G50= | Silent (SNP) | VAF 4/60 reads (7%) | catalogued as COSV99643429; called by muse, mutect2
- APBB3 | c.290+56G>T | Intron (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- EMC3-AS1 | n.470C>A | RNA (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- HPS4 | c.*942G>T | 3'UTR (SNP) | VAF 6/46 reads (13%) | called by muse, mutect2
- JAZF1 | c.189-18034G>T | Intron (SNP) | VAF 4/36 reads (11%) | catalogued as rs1398255938; called by muse, mutect2
